Surgical pathology report (de-identified scan), TCGA case TCGA-27-1835, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1835-01A (Primary Tumor).

Ref. Number

Gender

Birth date

Tumor site

Left temporal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file 71af72d4-8532-4246-bd24-fb3726f1021e (TCGA-27-1835.5F1DE659-7D7F-4A96-A9FC-058EFF128012.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).